Surgical pathology report (de-identified scan), TCGA case TCGA-5R-AAAM, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Proteogenex, Inc, specimen TCGA-5R-AAAM-01A (Primary Tumor).

ICD-O.3

Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
9/5/21/14

Age/Sex: years / F

Date:

Procedure: Resection of the liver

Preoperative diagnosis: CARCINOMA OF THE LIVER

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. LIVER, SEGMENT I 2. HILAR LYMPH NODES

Diagnosis:

1. LIVER, SEGMENT I:

- Moderately differentiated hepatocellular carcinoma
- Satellites
- Vascular invasion is present
- Remaining hepatic tissue shows micronodular cirrhosis (Metavir fibrosis score 4, Knodell histological activity index score 4, Ishak fibrosis score 6)
- Resection margin is free of tumor

2. HILAR LYMPH NODES:

- Lymph node is negative for metastatic carcinoma

Gross description:

1. LIVER, SEGMENT I:

Received fresh, is a part of the liver 7.5 x 5.0 x 2.0 cm in dimensions. At a distance of 1.5 cm from the resection margin the well-circumscribed lobulated brown-gray tumor 3.2 x 2.2 x 3.0 cm in dimensions is present. In the surrounding hepatic tissue there are two similar lesions 0.3 and 0.7 cm in diameter. The remaining hepatic tissue consists of firm brownish nodules ranging from 0.1 to 0.3 cm in diameter.

2. HILAR LYMPH NODES:

Received fresh, is a portion of adipose tissue with a lymph node 1.3 cm in greatest dimension.

Source: NCI Genomic Data Commons file 039dc220-3c6b-43eb-ae8a-a32dd4bf7a84 (TCGA-5R-AAAM.B07C5DBA-634E-4028-A32D-61FE7445BDEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).